Somatic mutation profile of tumor specimen ALCH-B027-TTR1-A (aliquot ALCH-B027-TTR1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B027, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.3 years (18,370 days).
Specimen ALCH-B027-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 170c43dc-b1fc-4e5d-acf7-81367e0efce3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B027-NB1-A (Blood Derived Normal), aliquot ALCH-B027-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37748723-6add-4ab5-ae43-060e3bf83a00

The open-access MAF lists 58 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, RNA 4, Nonsense Mutation 3, 3'UTR 2, Intron 2, Splice Region 1, In Frame Del 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA1 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 14/149 reads (9%) | catalogued as rs369717052, CM1511726, COSV62057121; ClinVar: pathogenic; called by muse, mutect2
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- EGFR | c.2235_2243del p.L747_E749del | In Frame Del (DEL) | VAF 58/398 reads (15%) | hotspot (GDC flag); catalogued as rs727504266; ClinVar: drug response; called by pindel, varscan2
- PTEN | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 284/873 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs121909223, CD097201, CM971271, COSV64288968, COSV64294667, COSV64296578, COSV64297040; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 88/392 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs768495202; called by muse, varscan2
- ADCY2 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1379866152, COSV57871123; called by muse, mutect2
- CHMP7 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1477163149, COSV57533892; called by muse, varscan2
- CNTNAP3 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1374325132, COSV52676102, COSV99905386; called by muse, mutect2, varscan2
- COL5A2 | c.1754G>C p.G585A | Missense Mutation (SNP) | VAF 449/958 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66409008, COSV66415961; called by muse, mutect2, varscan2
- DOCK3 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1341159051; called by muse, mutect2, varscan2
- FBXO4 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV55852431; called by muse, mutect2, varscan2
- HDAC9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 83/350 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1400537160, COSV67769993; called by muse, varscan2
- NAT14 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs867370804; called by muse, mutect2
- PCDH17 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749253149; called by muse, mutect2, varscan2
- PRSS36 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as rs778099836; called by muse, mutect2, varscan2
- SMC4 | c.2086T>G p.L696V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV61006367; called by muse, mutect2
- TENM2 | c.4196G>A p.R1399Q (on ENST00000518659 / NM_001122679.2; = p.R1160Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs1489815338; called by muse, mutect2
- TP63 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM056707; called by muse, mutect2, varscan2
- USP34 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); catalogued as rs970997261, COSV68401706; called by muse, varscan2
- WDR49 | c.67C>A p.H23N (on ENST00000308378 / NM_001366158.1; = p.H364N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as COSV57708840; called by muse, varscan2
- ZBTB22 | c.1346C>G p.A449G | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1348598888; called by muse, mutect2, varscan2
- ZNF865 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.21); catalogued as rs1302056971; called by muse, mutect2
- ACAP2 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 107/559 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL2 | c.3958C>A p.H1320N (on ENST00000370717 / NM_001366005.1; = p.H1264N on NM_012302.4) | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CACNA1E | c.6280T>C p.S2094P (on ENST00000367573 / NM_001205293.3; = p.S2051P on NM_000721.4) | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); called by muse, mutect2
- CATSPERB | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2
- CRTC3 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV3-43 | c.305T>C p.M102T | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); called by muse, varscan2
- KCNAB2 | c.165A>G p.G55= | Splice Region (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- KIAA2012 | c.3286C>T p.R1096W | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2
- LCE1D | c.71G>A p.C24Y | Missense Mutation (SNP) | VAF 65/261 reads (25%) | PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- MACC1 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MAL | c.378T>G p.I126M | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MTMR8 | c.362A>T p.E121V | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- NISCH | c.670A>T p.I224L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POU2F1 | c.1261G>A p.E421K (on ENST00000541643 / NM_001365848.1; = p.E444K on NM_002697.4) | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RTN1 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 31/235 reads (13%) | called by muse, mutect2, varscan2
- SCN10A | c.4211T>G p.F1404C | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53 | c.909_912del p.S303Rfs*41 | Frame Shift Del (DEL) | VAF 78/328 reads (24%) | called by mutect2, pindel, varscan2
- USP6 | c.2619C>G p.Y873* | Nonsense Mutation (SNP) | VAF 18/161 reads (11%) | called by muse, mutect2, varscan2
- ABTB1 | c.1311C>T p.I437= (on ENST00000232744 / NM_172027.3; = p.I295= on NM_032548.3) | Silent (SNP) | VAF 58/233 reads (25%) | catalogued as rs1368464989; called by muse, mutect2, varscan2
- AVPR1B | c.171G>A p.L57= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, varscan2
- BCL9 | c.2859C>T p.P953= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs782309609, COSV52341398; called by muse, mutect2
- CRACD | c.2466C>T p.S822= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs200636394, COSV51718667; called by muse, mutect2, varscan2
- DACT1 | c.1557C>A p.P519= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV60019236; called by muse, mutect2, varscan2
- KCNS3 | c.603C>T p.A201= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as rs1467277569; called by muse, mutect2, varscan2
- KRTAP16-1 | c.474T>C p.I158= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as rs770510762; called by muse, mutect2
- REL | c.1428C>A p.S476= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV54363643; called by muse, mutect2, varscan2
- VOPP1 | c.252C>T p.R84= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs1284736028; called by muse, mutect2, varscan2
- DPPA3P2 | n.298A>G | RNA (SNP) | VAF 27/262 reads (10%) | catalogued as rs1320382046; called by muse, varscan2
- GAS8 | c.*276C>T | 3'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as rs1258192594; called by mutect2, varscan2
- LINC00587 | n.392A>G | RNA (SNP) | VAF 24/167 reads (14%) | called by muse, mutect2, varscan2
- LINC02610 | n.3013A>G | RNA (SNP) | VAF 15/197 reads (8%) | called by muse, mutect2
- STK4 | c.1306-21908G>A | Intron (SNP) | VAF 20/261 reads (8%) | called by muse, mutect2
- UQCRB | c.*867G>C | 3'UTR (SNP) | VAF 5/48 reads (10%) | catalogued as rs1246472599; called by muse, mutect2
- ZNF429 | chr19:21541869 C>G | 3'Flank (SNP) | VAF 4/22 reads (18%) | catalogued as rs1359750158; called by mutect2, varscan2
- ZNF849P | n.1094T>C | RNA (SNP) | VAF 130/484 reads (27%) | called by muse, varscan2
- ZRSR2 | c.203+1339del | Intron (DEL) | VAF 5/42 reads (12%) | called by pindel, varscan2
